Somatic mutation profile of cancer-model specimen HCM-WCMC-0948-C67-85A (3D Organoid; aliquot HCM-WCMC-0948-C67-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-WCMC-0948-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 84.0 years (30,697 days).
Specimen HCM-WCMC-0948-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7a218f3-d4fb-4bed-8534-a8643ed56874.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0948-C67-11A (FFPE Scrolls), aliquot HCM-WCMC-0948-C67-11A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae68a6c7-bc66-4712-a857-e2aae17d7a83

The open-access MAF lists 394 somatic variants for this specimen: 280 protein-altering or splice-affecting, 100 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 239, Silent 100, Nonsense Mutation 26, Frame Shift Del 6, Intron 5, RNA 4, Splice Site 2, Frame Shift Ins 2, Splice Region 2, 5'UTR 2, 5'Flank 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IFT172 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 34/644 reads (5%) | catalogued as rs1250676888; ClinVar: pathogenic; called by muse, mutect2
- SLC4A1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 191/628 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121912757, CM004839; ClinVar: pathogenic / uncertain significance / benign; called by muse, mutect2, varscan2
- ADAMTS1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 778/1058 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs768912751; called by muse, mutect2, varscan2
- ADGRV1 | c.8743G>C p.E2915Q | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67986059; called by muse, mutect2, varscan2
- AFAP1L1 | c.327C>T p.N109= | Splice Region (SNP) | VAF 27/276 reads (10%) | catalogued as rs532471533, COSV57044130; called by muse, mutect2
- AHDC1 | c.2293G>C p.G765R | Missense Mutation (SNP) | VAF 506/721 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV55938083; called by muse, mutect2, varscan2
- AHNAK2 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 390/391 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs759359031; called by muse, mutect2, varscan2
- AMY2B | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs142179530; called by muse, mutect2
- ANAPC2 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 39/483 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1441997576, COSV100118843, COSV60572913; called by muse, mutect2
- AP3D1 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 181/430 reads (42%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.884); catalogued as COSV61430219; called by muse, mutect2, varscan2
- ARMC4 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 66/613 reads (11%) | catalogued as COSV59476760; called by muse, mutect2, varscan2
- BSPRY | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 37/597 reads (6%) | catalogued as COSV65243275; called by muse, mutect2
- BSPRY | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 38/528 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99445148; called by muse, mutect2
- BTBD6 | c.1423G>T p.G475C | Missense Mutation (SNP) | VAF 346/347 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100527804; called by muse, mutect2, varscan2
- C8orf33 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58895254; called by muse, mutect2, varscan2
- C8orf34 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 137/386 reads (35%) | catalogued as rs866337168; called by muse, mutect2, varscan2
- CALD1 | c.1835G>C p.R612T (on ENST00000361675 / NM_033138.4; = p.R357T on NM_004342.7) | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV62647035; called by muse, mutect2, varscan2
- CCDC180 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as rs750044356, COSV100826481; called by muse, mutect2, varscan2
- CD109 | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 200/657 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV54645579; called by muse, mutect2, varscan2
- CDH7 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV59892340; called by muse, mutect2, varscan2
- CEACAM18 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV101140441; called by muse, mutect2, varscan2
- CHD6 | c.6456C>A p.N2152K | Missense Mutation (SNP) | VAF 38/633 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs760966128, COSV64691341; called by muse, mutect2
- CPXM2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 66/561 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs909638407; called by muse, mutect2, varscan2
- CSMD1 | c.3661C>A p.P1221T (on ENST00000520002; = p.P1220T on NM_033225.6) | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59360927; called by muse, mutect2, varscan2
- DLGAP4 | c.1868G>T p.R623L | Missense Mutation (SNP) | VAF 58/866 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.195); catalogued as COSV59420026; called by muse, mutect2
- DNAH11 | c.10855G>C p.E3619Q | Missense Mutation (SNP) | VAF 238/287 reads (83%) | SIFT tolerated (0.32); PolyPhen benign (0.272); catalogued as COSV100180714; called by muse, mutect2, varscan2
- ELOA2 | c.1635C>A p.S545R | Missense Mutation (SNP) | VAF 42/720 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV55304760; called by muse, mutect2
- ENO2 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 184/440 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV50389461; called by muse, mutect2, varscan2
- EPHA5 | c.2809C>T p.R937C | Missense Mutation (SNP) | VAF 163/273 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs142359231, COSV56673676; called by muse, mutect2, varscan2
- FAM151A | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56362847; called by muse, mutect2, varscan2
- FAT2 | c.9893C>G p.S3298C | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55830182; called by muse, mutect2
- FNIP1 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 19/273 reads (7%) | catalogued as COSV100330576; called by muse, mutect2
- FOXD3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as rs764763503; called by muse, mutect2
- FOXN3 | c.988G>A p.D330N (on ENST00000261302; = p.D308N on NM_005197.4) | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs780882135; called by muse, mutect2
- GEN1 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 225/225 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV58056563; called by muse, mutect2, varscan2
- GPS2 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 233/233 reads (100%) | catalogued as rs745671551, COSV59750274, COSV59751290; called by muse, mutect2, varscan2
- HIPK2 | c.3241G>A p.G1081S | Missense Mutation (SNP) | VAF 50/768 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs781161791, COSV69210654; called by muse, mutect2
- HIVEP3 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 469/597 reads (79%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV56025023; called by muse, mutect2, varscan2
- HIVEP3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 41/860 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1376638578, COSV56019729; called by muse, mutect2
- HSPA5 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 268/270 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52335350; called by muse, mutect2, varscan2
- INPP5F | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs374196186; called by muse, mutect2, varscan2
- IRF6 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 42/491 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM022390, CM092335, COSV100884042, COSV65419096, COSV65419721; called by muse, mutect2
- ITK | c.1382G>A p.G461D | Missense Mutation (SNP) | VAF 297/384 reads (77%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.688); catalogued as COSV70064713; called by muse, mutect2, varscan2
- IZUMO1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 66/704 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs967220957; called by muse, mutect2
- KCNH5 | c.1539G>C p.W513C | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59769197; called by muse, mutect2, varscan2
- KCNJ4 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 35/676 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1035975043; called by muse, mutect2
- KCNK1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 84/660 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as rs766786842; called by muse, mutect2, varscan2
- KCNK1 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 205/248 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292374624; called by muse, mutect2, varscan2
- KMT2D | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 117/334 reads (35%) | catalogued as COSV56441661; called by muse, mutect2, varscan2
- LGI2 | c.1464G>C p.Q488H | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.771); catalogued as COSV66122572; called by muse, mutect2, varscan2
- LLGL1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 40/556 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372430699; called by muse, mutect2
- LRRC14 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 48/755 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs755143736; called by muse, mutect2
- LRRC32 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 58/694 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs752043854; called by muse, mutect2
- MRPS15 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 71/372 reads (19%) | catalogued as COSV64152307; called by muse, mutect2, varscan2
- MUC16 | c.25741G>A p.E8581K | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as COSV67449464, COSV67452321; called by muse, mutect2
- MUC4 | c.12625C>T p.L4209F | Missense Mutation (SNP) | VAF 505/1287 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as rs1431589968; called by muse, mutect2, varscan2
- MZF1 | c.2188G>A p.V730I | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.022); catalogued as COSV53042765; called by muse, mutect2
- NHLH1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 669/1083 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99042927; called by muse, mutect2, varscan2
- NPTX1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 60/982 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747838744; called by muse, mutect2
- OR1S1 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 46/610 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100515416, COSV58708019; called by muse, mutect2
- OR4Q3 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 196/975 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100057291; called by muse, mutect2, varscan2
- OR8I2 | c.808G>C p.A270P | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56170504; called by muse, mutect2
- PDCL3 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV51809645; called by muse, mutect2, varscan2
- PDZRN4 | c.2740C>A p.R914S (on ENST00000402685 / NM_001164595.2; = p.R656S on NM_013377.4) | Missense Mutation (SNP) | VAF 211/442 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54191734; called by muse, mutect2, varscan2
- PENK | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 230/639 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs149421409; called by muse, mutect2, varscan2
- PHOX2A | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 66/948 reads (7%) | catalogued as rs1045829640; called by muse, mutect2
- PLAAT5 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 70/585 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs1428490678; called by muse, mutect2, varscan2
- PLEC | c.7153G>A p.E2385K (on ENST00000322810 / NM_201380.4; = p.E2275K on NM_000445.5) | Missense Mutation (SNP) | VAF 66/598 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1554691569, COSV100510051, COSV59667101, COSV59697472; ClinVar: uncertain significance; called by muse, varscan2
- PRDM9 | c.1720C>T p.H574Y | Missense Mutation (SNP) | VAF 86/662 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376222750; called by muse, mutect2, varscan2
- PRSS37 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 61/483 reads (13%) | catalogued as COSV100633837; called by muse, mutect2, varscan2
- PSME4 | c.2766G>C p.K922N | Missense Mutation (SNP) | VAF 278/278 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101122630; called by muse, mutect2, varscan2
- RBM46 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55981340; called by muse, mutect2, varscan2
- RGS11 | c.1115G>A p.R372Q (on ENST00000397770 / NM_183337.3; = p.R351Q on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/554 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs371409840; called by muse, mutect2, varscan2
- SCAPER | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1299479056; called by muse, mutect2
- SERBP1 | c.160G>C p.A54P | Missense Mutation (SNP) | VAF 98/943 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.639); catalogued as COSV63414452; called by muse, varscan2
- SEZ6L | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.606); catalogued as COSV50701162; called by muse, mutect2, varscan2
- SHANK1 | c.5942G>A p.R1981H | Missense Mutation (SNP) | VAF 243/837 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs200050673; called by muse, mutect2, varscan2
- SLC22A7 | c.1389G>C p.Q463H (on ENST00000372585 / NM_153320.2; = p.Q461H on NM_006672.3) | Missense Mutation (SNP) | VAF 169/406 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746383922; called by muse, mutect2, varscan2
- SLC35A2 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 83/503 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.798); catalogued as rs374840868; ClinVar: uncertain significance; called by muse, varscan2
- SLC7A3 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs775658540; called by muse, mutect2, varscan2
- SPTAN1 | c.3576G>A p.W1192* | Nonsense Mutation (SNP) | VAF 194/194 reads (100%) | catalogued as COSV100823570; called by muse, varscan2
- STAB1 | c.2869G>A p.G957S | Missense Mutation (SNP) | VAF 250/786 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760302220, COSV58733221; called by muse, mutect2, varscan2
- SUFU | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1303650670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC2 | c.8414C>T p.S2805L (on ENST00000334433; = p.S883L on NM_006997.4) | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99586403; called by muse, mutect2, varscan2
- TASOR | c.3191C>T p.S1064L (on ENST00000355628 / NM_001365636.2; = p.S688L on NM_015224.3) | Missense Mutation (SNP) | VAF 205/369 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.442); catalogued as rs529203959; called by muse, mutect2, varscan2
- TCP11 | c.826C>T p.P276S (on ENST00000512012; = p.P214S on NM_018679.5) | Missense Mutation (SNP) | VAF 233/384 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV55133395; called by muse, mutect2, varscan2
- TM9SF4 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs769762559; called by muse, mutect2, varscan2
- TNN | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53433923; called by muse, mutect2
- TNRC6C | c.3439C>A p.H1147N | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV56947768; called by muse, mutect2
- TNXB | c.6772G>A p.E2258K (on ENST00000647633; = p.E2011K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1434254207, COSV64478989; called by muse, mutect2, varscan2
- TOGARAM1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 88/485 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.443); catalogued as COSV61888665; called by muse, mutect2, varscan2
- TP53 | c.1007del p.E336Gfs*9 | Frame Shift Del (DEL) | VAF 292/294 reads (99%) | catalogued as COSV53494581; called by mutect2, varscan2
- TP53BP2 | c.2012C>T p.S671F (on ENST00000343537 / NM_001031685.3; = p.S542F on NM_005426.2) | Missense Mutation (SNP) | VAF 294/318 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV59069206; called by muse, varscan2
- TPRN | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 102/1072 reads (10%) | catalogued as rs1169297134; called by muse, mutect2
- TRNAU1AP | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100867941, COSV65777738; called by muse, mutect2, varscan2
- TRPC4 | c.1474C>G p.L492V | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs771803131; called by muse, mutect2, varscan2
- TSPEAR | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 75/1044 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV59973940; called by muse, mutect2
- TTLL10 | c.980G>T p.R327L (on ENST00000379289 / NM_001130045.2; = p.R254L on NM_153254.3) | Missense Mutation (SNP) | VAF 84/876 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs546816658, COSV101016758; called by muse, mutect2
- TTLL7 | c.2402C>G p.P801R | Missense Mutation (SNP) | VAF 23/360 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV53085644; called by muse, mutect2
- TTN | c.71435C>A p.T23812K (on ENST00000591111; = p.T16388K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/317 reads (4%) | PolyPhen benign (0.003); catalogued as rs1272812744; ClinVar: uncertain significance; called by muse, mutect2
- TYW5 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 522/523 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1333471562; called by muse, mutect2, varscan2
- VPS8 | c.4019C>A p.S1340* (on ENST00000625842 / NM_001349294.1; = p.S1338* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/294 reads (3%) | catalogued as COSV54987122; called by muse, mutect2
- WDFY3 | c.4433C>T p.S1478F | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99882453; called by muse, mutect2, varscan2
- WNK2 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 139/849 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52931296; called by muse, mutect2, varscan2
- ZFP92 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 76/612 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs1556975110, COSV58598372; called by muse, mutect2, varscan2
- ZNF275 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.136); catalogued as rs782140192; called by muse, mutect2, varscan2
- ZNF436 | c.1029C>G p.F343L | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1285568114, COSV58359353; called by muse, mutect2
- ZNF653 | c.689C>G p.P230R | Missense Mutation (SNP) | VAF 64/659 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.273); catalogued as COSV53402281; called by muse, mutect2
- ZNF729 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1365659125; called by muse, mutect2
- ZNF746 | c.1756C>A p.R586S | Missense Mutation (SNP) | VAF 703/816 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV61408480; called by muse, mutect2, varscan2
- ZSWIM9 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 525/729 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs886477598; called by muse, mutect2, varscan2
- ADNP | c.3217G>A p.D1073N | Missense Mutation (SNP) | VAF 21/554 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.26); called by muse, mutect2
- AHDC1 | c.3364G>C p.E1122Q | Missense Mutation (SNP) | VAF 368/475 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- AHDC1 | c.2106G>T p.K702N | Missense Mutation (SNP) | VAF 476/645 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- AHDC1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 456/587 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHDC1 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 465/630 reads (74%) | called by muse, mutect2, varscan2
- AHNAK2 | c.6358G>A p.E2120K | Missense Mutation (SNP) | VAF 479/480 reads (100%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARSJ | c.1488C>A p.F496L | Missense Mutation (SNP) | VAF 105/327 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB2 | c.167+1G>T p.X56_splice | Splice Site (SNP) | VAF 22/455 reads (5%) | called by muse, mutect2
- ASTN2 | c.3418G>T p.G1140C (on ENST00000313400 / NM_001365069.1; = p.G1089C on NM_014010.5) | Missense Mutation (SNP) | VAF 29/463 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATAD1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ATF7IP | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 31/435 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- ATP10A | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 266/332 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AVL9 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 26/350 reads (7%) | called by muse, mutect2
- B4GALNT1 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 302/572 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEND7 | c.677C>G p.S226* | Nonsense Mutation (SNP) | VAF 54/1060 reads (5%) | called by muse, mutect2
- BTG4 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C10orf67 | c.349G>C p.D117H (on ENST00000323327; = p.D118H on NM_153714.3) | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- C1orf54 | c.190-1G>C p.X64_splice | Splice Site (SNP) | VAF 37/343 reads (11%) | called by muse, mutect2, varscan2
- C8orf76 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 70/1195 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2
- CABP7 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 50/317 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- CACNA1I | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- CALML3 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 134/1558 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CCDC38 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CCER2 | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 57/852 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- CCT6B | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 95/168 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, varscan2
- CEP170B | c.2221G>A p.E741K (on ENST00000453495; = p.E670K on NM_015005.3) | Missense Mutation (SNP) | VAF 130/722 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP350 | c.1506G>C p.K502N | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CEP68 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2
- CFHR1 | c.127dup p.S43Ffs*14 | Frame Shift Ins (INS) | VAF 23/150 reads (15%) | called by mutect2, varscan2
- CGB8 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 22/934 reads (2%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- CLEC16A | c.375_381del p.I126Ffs*19 | Frame Shift Del (DEL) | VAF 32/274 reads (12%) | called by mutect2, varscan2
- COL14A1 | c.4636C>G p.R1546G | Missense Mutation (SNP) | VAF 48/804 reads (6%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.7); called by muse, mutect2
- CRTC3 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 20/768 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSMD3 | c.5932C>G p.Q1978E (on ENST00000297405 / NM_001363185.1; = p.Q1874E on NM_052900.3) | Missense Mutation (SNP) | VAF 259/384 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CTRC | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 253/316 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP17A1 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DAW1 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2
- DDHD1 | c.1478C>G p.S493* (on ENST00000323669; = p.S690* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 42/203 reads (21%) | called by muse, mutect2, varscan2
- DENND4C | c.4738C>T p.P1580S (on ENST00000434457 / NM_001330640.2; = p.P1531S on NM_017925.7) | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIS3L | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 361/435 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- DMBT1 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 346/606 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- DNAH12 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 107/324 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DNAH9 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 496/496 reads (100%) | called by muse, mutect2, varscan2
- DNMBP | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAML1 | c.2630C>T p.P877L (on ENST00000321322; = p.P817L on NM_020693.4) | Missense Mutation (SNP) | VAF 53/714 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- DUSP6 | c.584_585del p.D195Gfs*2 | Frame Shift Del (DEL) | VAF 185/396 reads (47%) | called by mutect2, varscan2
- EDC4 | c.27C>G p.I9M | Missense Mutation (SNP) | VAF 429/790 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, varscan2
- ENTPD3 | c.1032C>G p.F344L | Missense Mutation (SNP) | VAF 193/363 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FLNC | c.6362G>T p.G2121V | Missense Mutation (SNP) | VAF 67/474 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FN3K | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 29/596 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2
- FNDC1 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 206/370 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FSIP2 | c.9096G>C p.Q3032H | Missense Mutation (SNP) | VAF 103/103 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAB1 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- GAL3ST4 | c.661_663dup p.E221dup | In Frame Ins (INS) | VAF 66/515 reads (13%) | called by mutect2, varscan2
- GLMP | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 606/680 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GPATCH8 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 24/449 reads (5%) | called by muse, mutect2
- GPR179 | c.2869C>T p.P957S (on ENST00000621958; = p.P956S on NM_001004334.4) | Missense Mutation (SNP) | VAF 60/972 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN2B | c.3255T>A p.Y1085* | Nonsense Mutation (SNP) | VAF 34/642 reads (5%) | called by muse, mutect2
- HECTD2 | c.1810del p.D604Ifs*22 | Frame Shift Del (DEL) | VAF 50/110 reads (45%) | called by mutect2, varscan2
- HECTD3 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 72/868 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.055); called by muse, mutect2
- HOXB6 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 296/1026 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- HSF5 | c.396C>G p.S132R | Missense Mutation (SNP) | VAF 72/920 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.104); called by muse, mutect2
- HSPA12B | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 251/606 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, varscan2
- ICE1 | c.5135C>G p.S1712C | Missense Mutation (SNP) | VAF 434/599 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL5 | c.264C>G p.F88L | Missense Mutation (SNP) | VAF 147/168 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ8 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 91/727 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- KCNQ3 | c.2433G>T p.Q811H | Missense Mutation (SNP) | VAF 96/1200 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- KERA | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2
- KLF2 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 253/515 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- KNTC1 | c.3548C>A p.T1183K | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.152); called by muse, mutect2
- KRT8 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 258/590 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LAMB2 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 177/862 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LINGO2 | c.1816A>G p.I606V | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- LRIT3 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, mutect2
- LRRC37A | c.2347C>G p.L783V | Missense Mutation (SNP) | VAF 274/1133 reads (24%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRRC9 | c.1793G>A p.C598Y | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- LZTR1 | c.2124C>G p.I708M | Missense Mutation (SNP) | VAF 42/667 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- MACF1 | c.836C>A p.P279Q | Missense Mutation (SNP) | VAF 13/207 reads (6%) | called by muse, mutect2
- MALRD1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 161/203 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MCMDC2 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 121/199 reads (61%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEF2C | c.1099G>T p.G367* | Nonsense Mutation (SNP) | VAF 24/174 reads (14%) | called by muse, varscan2
- MICAL1 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 59/802 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2
- MIGA2 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 31/472 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.224); called by muse, mutect2
- MITF | c.876A>G p.T292= (on ENST00000448226 / NM_006722.3; = p.T186= on NM_000248.4) | Splice Region (SNP) | VAF 35/404 reads (9%) | called by muse, mutect2
- MLLT6 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 190/627 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- MMP21 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 292/530 reads (55%) | called by muse, varscan2
- MYCBP2 | c.7014G>T p.M2338I (on ENST00000357337; = p.M2376I on NM_015057.5) | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- MYH10 | c.5742C>G p.N1914K | Missense Mutation (SNP) | VAF 72/551 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO1E | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 335/406 reads (83%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NARS1 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NARS1 | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, varscan2
- NARS1 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- NAXE | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 82/910 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- NPHS1 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 203/874 reads (23%) | called by muse, mutect2, varscan2
- NPIPB11 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 85/702 reads (12%) | called by mutect2, varscan2
- OLIG2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 46/1186 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- OR11H2 | c.43G>C p.E15Q (on ENST00000556246; = p.E26Q on NM_001197287.1) | Missense Mutation (SNP) | VAF 40/1062 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2
- OR7C1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 31/325 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.616); called by muse, mutect2
- PCDH8 | c.2617G>A p.G873S | Missense Mutation (SNP) | VAF 43/584 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.506); called by muse, mutect2
- PCM1 | c.2922G>C p.Q974H | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDCD4 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PDILT | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 26/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PELP1 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- PHGDH | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 224/329 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PHLPP2 | c.3298G>C p.E1100Q | Missense Mutation (SNP) | VAF 383/572 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PKD1L3 | c.1214A>C p.Q405P | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2
- PLA2G4A | c.1011C>G p.D337E | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- PNMA2 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 225/225 reads (100%) | SIFT tolerated (1); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PNPO | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 370/532 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRICKLE1 | c.998G>C p.S333T | Missense Mutation (SNP) | VAF 203/469 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRKDC | c.924del p.A311Lfs*10 | Frame Shift Del (DEL) | VAF 133/326 reads (41%) | called by mutect2, varscan2
- PRKDC | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 35/799 reads (4%) | called by muse, mutect2
- PTCHD4 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 56/588 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- PTRHD1 | c.170C>A p.A57E | Missense Mutation (SNP) | VAF 73/1342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- RAVER1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 97/682 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RGS20 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RIMS1 | c.2768del p.P923Qfs*2 | Frame Shift Del (DEL) | VAF 56/336 reads (17%) | called by mutect2, varscan2
- RIPK1 | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 162/249 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- RNF114 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RPL7A | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SAMD15 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SARDH | c.1029C>G p.D343E | Missense Mutation (SNP) | VAF 50/491 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2
- SEMA3C | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.326); called by muse, mutect2
- SF1 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 128/236 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A1 | c.1354A>G p.T452A | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- SLC24A1 | c.2950A>T p.I984F | Missense Mutation (SNP) | VAF 36/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- SLC25A1 | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 68/592 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC25A34 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 51/596 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2
- SLC2A6 | c.788C>G p.S263W | Missense Mutation (SNP) | VAF 46/620 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC6A11 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 337/769 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLU7 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SOX10 | c.651dup p.G218Rfs*63 | Frame Shift Ins (INS) | VAF 311/542 reads (57%) | called by mutect2, varscan2
- SOX10 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 322/558 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by mutect2, varscan2
- SPINDOC | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 174/453 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBKBP1 | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 60/923 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- TENT4A | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.55); called by muse, mutect2
- TICRR | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- TKTL2 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 37/533 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2
- TMEM62 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 93/127 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNC | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 709/709 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC6B | c.1782G>T p.R594S | Missense Mutation (SNP) | VAF 33/496 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- TNRC6C | c.1970A>T p.E657V | Missense Mutation (SNP) | VAF 41/623 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TOP2A | c.4499T>C p.M1500T | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRBV30 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 289/331 reads (87%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, varscan2
- TSEN34 | c.659G>C p.R220P | Missense Mutation (SNP) | VAF 82/1036 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTBK1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 220/396 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC1 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2
- TTN | c.75062T>A p.I25021N (on ENST00000591111; = p.I17597N on NM_003319.4) | Missense Mutation (SNP) | VAF 57/198 reads (29%) | PolyPhen benign (0.106); called by muse, mutect2, varscan2
- UBE2QL1 | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 110/708 reads (16%) | called by muse, mutect2, varscan2
- UBE4A | c.2589G>C p.E863D (on ENST00000252108 / NM_001204077.2; = p.E870D on NM_004788.4) | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, varscan2
- UBR3 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.14); called by muse, mutect2
- UNC79 | c.7874C>T p.S2625F (on ENST00000393151 / NM_001346218.2; = p.S2448F on NM_020818.5) | Missense Mutation (SNP) | VAF 40/644 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- UNK | c.1691G>A p.G564D | Missense Mutation (SNP) | VAF 37/951 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS4A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- VSIG10L | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 202/816 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, varscan2
- VWA2 | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWA3B | c.3122T>A p.I1041N | Missense Mutation (SNP) | VAF 174/175 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR13 | c.308_319del p.L103_G107delinsR | In Frame Del (DEL) | VAF 32/326 reads (10%) | called by mutect2, varscan2
- ZCCHC3 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 364/736 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZFAT | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 34/992 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- ZNF285 | c.634A>G p.N212D | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ZNF43 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ZNF43 | c.1503G>C p.K501N | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF469 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 48/776 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.172); called by muse, mutect2
- ZNF549 | c.564G>C p.E188D (on ENST00000376233 / NM_001199295.2; = p.E175D on NM_153263.2) | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- ZNF638 | c.3050C>G p.P1017R | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF865 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 210/796 reads (26%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- ZNF98 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); called by muse, mutect2
- AC093512.2 | c.396C>G p.L132= | Silent (SNP) | VAF 363/648 reads (56%) | called by muse, mutect2, varscan2
- ACVRL1 | c.366C>T p.I122= | Silent (SNP) | VAF 302/862 reads (35%) | called by muse, mutect2, varscan2
- AHDC1 | c.1191G>C p.R397= | Silent (SNP) | VAF 469/638 reads (74%) | called by muse, mutect2, varscan2
- AHNAK2 | c.5805G>C p.L1935= | Silent (SNP) | VAF 376/376 reads (100%) | catalogued as COSV60932796; called by muse, varscan2
- ARHGAP26 | c.2415C>T p.L805= | Silent (SNP) | VAF 33/427 reads (8%) | called by muse, mutect2
- ATP1A2 | c.2742G>A p.T914= | Silent (SNP) | VAF 321/913 reads (35%) | catalogued as rs201215311, COSV63403470; called by muse, varscan2
- ATP5PF | c.174A>T p.G58= | Silent (SNP) | VAF 90/409 reads (22%) | called by muse, mutect2, varscan2
- BCAR1 | c.18C>T p.F6= | Silent (SNP) | VAF 57/537 reads (11%) | catalogued as rs958432935; called by muse, mutect2, varscan2
- BICDL1 | c.1680C>T p.I560= | Silent (SNP) | VAF 151/341 reads (44%) | catalogued as rs201184033, COSV57494332; called by muse, mutect2, varscan2
- CBFA2T3 | c.1338G>A p.K446= | Silent (SNP) | VAF 54/932 reads (6%) | called by muse, mutect2
- CCER1 | c.444C>T p.R148= | Silent (SNP) | VAF 117/1030 reads (11%) | catalogued as COSV62646982; called by muse, mutect2, varscan2
- CHL1 | c.1200G>A p.Q400= (on ENST00000397491 / NM_001253387.1; = p.Q416= on NM_006614.4) | Silent (SNP) | VAF 36/542 reads (7%) | called by muse, mutect2
- CPB1 | c.522T>C p.G174= | Silent (SNP) | VAF 15/469 reads (3%) | called by muse, mutect2
- DIDO1 | c.4044C>T p.T1348= | Silent (SNP) | VAF 209/479 reads (44%) | catalogued as COSV56612710; called by muse, varscan2
- DNAH3 | c.3057G>A p.T1019= | Silent (SNP) | VAF 258/499 reads (52%) | catalogued as rs764514972; called by muse, mutect2, varscan2
- DNAH5 | c.13008C>T p.I4336= | Silent (SNP) | VAF 29/687 reads (4%) | catalogued as rs1416805485; called by muse, mutect2
- DSP | c.4899C>T p.L1633= | Silent (SNP) | VAF 119/322 reads (37%) | catalogued as rs876657459; called by muse, mutect2, varscan2
- EP400 | c.1146C>A p.V382= | Silent (SNP) | VAF 28/372 reads (8%) | catalogued as COSV57771820; called by muse, mutect2
- EPPK1 | c.1251C>T p.A417= | Silent (SNP) | VAF 226/497 reads (45%) | catalogued as rs782189602; called by muse, mutect2, varscan2
- FAM171A2 | c.1209C>T p.S403= | Silent (SNP) | VAF 593/866 reads (68%) | called by muse, mutect2, varscan2
- FAT2 | c.5514C>T p.F1838= | Silent (SNP) | VAF 42/229 reads (18%) | catalogued as COSV99942524; called by muse, mutect2, varscan2
- FCGRT | c.255G>A p.E85= | Silent (SNP) | VAF 148/604 reads (25%) | called by muse, mutect2, varscan2
- GAREM2 | c.2286G>T p.L762= | Silent (SNP) | VAF 56/1321 reads (4%) | called by muse, mutect2
- GDF2 | c.852C>G p.L284= | Silent (SNP) | VAF 43/667 reads (6%) | catalogued as rs782098307; called by muse, mutect2
- GLYATL3 | c.150G>A p.P50= | Silent (SNP) | VAF 23/295 reads (8%) | catalogued as rs139674506; called by muse, mutect2
- GLYR1 | c.12G>A p.V4= | Silent (SNP) | VAF 408/550 reads (74%) | catalogued as rs951333418; called by muse, mutect2, varscan2
- GPR17 | c.114T>C p.G38= | Silent (SNP) | VAF 40/420 reads (10%) | called by muse, mutect2
- GPR83 | c.819C>T p.G273= | Silent (SNP) | VAF 156/501 reads (31%) | catalogued as rs771867380; called by muse, mutect2, varscan2
- GTPBP3 | c.1056C>A p.T352= | Silent (SNP) | VAF 41/616 reads (7%) | catalogued as rs1035729758; called by muse, mutect2
- H2AX | c.381G>C p.P127= | Silent (SNP) | VAF 142/449 reads (32%) | called by muse, mutect2, varscan2
- HMCN1 | c.12087C>T p.N4029= | Silent (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- HOOK2 | c.540A>G p.L180= | Silent (SNP) | VAF 14/295 reads (5%) | called by muse, mutect2
- HSPA12B | c.1305G>A p.V435= | Silent (SNP) | VAF 212/478 reads (44%) | catalogued as rs1256186376; called by muse, mutect2, varscan2
- IFNGR1 | c.1110T>C p.H370= | Silent (SNP) | VAF 18/510 reads (4%) | called by muse, mutect2
- IGBP1P2 | c.774C>T p.G258= | Silent (SNP) | VAF 44/576 reads (8%) | catalogued as rs1356820187; called by muse, mutect2
- IGF1R | c.1975C>A p.R659= | Silent (SNP) | VAF 30/353 reads (8%) | catalogued as COSV51346746; called by muse, mutect2
- IQGAP1 | c.975C>T p.F325= | Silent (SNP) | VAF 76/460 reads (17%) | called by muse, varscan2
- ISOC1 | c.796C>T p.L266= | Silent (SNP) | VAF 40/416 reads (10%) | called by muse, mutect2
- ITPRIPL2 | c.273C>T p.H91= | Silent (SNP) | VAF 481/925 reads (52%) | catalogued as rs1401585391; called by muse, mutect2, varscan2
- ITSN1 | c.4992C>T p.F1664= | Silent (SNP) | VAF 48/702 reads (7%) | catalogued as rs201592908; called by muse, mutect2
- KCNQ3 | c.276G>A p.P92= | Silent (SNP) | VAF 50/1418 reads (4%) | catalogued as COSV66472500; called by muse, mutect2
- LETM1 | c.135G>A p.R45= | Silent (SNP) | VAF 84/335 reads (25%) | called by muse, mutect2, varscan2
- LRRC74B | c.1134G>A p.L378= | Silent (SNP) | VAF 18/509 reads (4%) | catalogued as rs1193090373; called by muse, mutect2
- MED16 | c.966C>T p.F322= | Silent (SNP) | VAF 191/392 reads (49%) | called by muse, mutect2, varscan2
- MID1 | c.1389C>G p.V463= | Silent (SNP) | VAF 403/403 reads (100%) | called by muse, mutect2, varscan2
- MTA3 | c.1713G>C p.L571= (on ENST00000405094 / NM_001330442.2; = p.L514= on NM_001282755.1) | Silent (SNP) | VAF 27/618 reads (4%) | called by muse, mutect2
- MTMR2 | c.918C>T p.I306= | Silent (SNP) | VAF 28/488 reads (6%) | called by muse, mutect2
- MYBPC2 | c.408C>G p.L136= | Silent (SNP) | VAF 116/480 reads (24%) | catalogued as COSV63094549; called by muse, mutect2
- MYO16 | c.3993C>T p.A1331= | Silent (SNP) | VAF 21/342 reads (6%) | called by muse, mutect2
- NBEA | c.3213C>G p.L1071= | Silent (SNP) | VAF 208/209 reads (100%) | catalogued as COSV59816499; called by muse, mutect2, varscan2
- NLRP5 | c.3186G>C p.S1062= | Silent (SNP) | VAF 138/474 reads (29%) | called by muse, mutect2, varscan2
- NRK | c.3513C>T p.F1171= | Silent (SNP) | VAF 42/201 reads (21%) | catalogued as rs765030639, COSV54602949; called by muse, mutect2, varscan2
- OBSCN | c.17394G>A p.T5798= | Silent (SNP) | VAF 27/506 reads (5%) | catalogued as rs781590309; called by muse, mutect2
- OR13G1 | c.501G>A p.G167= | Silent (SNP) | VAF 39/376 reads (10%) | catalogued as COSV100687158; called by muse, varscan2
- OR8D4 | c.90C>G p.L30= | Silent (SNP) | VAF 183/295 reads (62%) | catalogued as COSV100361910; called by muse, mutect2, varscan2
- P3H1 | c.1791C>T p.T597= | Silent (SNP) | VAF 78/627 reads (12%) | called by muse, mutect2, varscan2
- PANK1 | c.135C>G p.P45= | Silent (SNP) | VAF 83/529 reads (16%) | called by muse, mutect2, varscan2
- PCDH19 | c.102C>T p.R34= | Silent (SNP) | VAF 55/463 reads (12%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1782C>T p.R594= | Silent (SNP) | VAF 99/649 reads (15%) | catalogued as rs782085408, COSV100252132; called by muse, mutect2, varscan2
- PDE1C | c.1194C>T p.F398= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as rs751777769; called by muse, mutect2, varscan2
- PDGFRA | c.1680G>A p.R560= | Silent (SNP) | VAF 20/223 reads (9%) | catalogued as rs760250543, COSV57274709; called by muse, mutect2, varscan2
- PDRG1 | c.132G>C p.L44= | Silent (SNP) | VAF 256/563 reads (45%) | catalogued as COSV52430986, COSV52431920; called by muse, mutect2, varscan2
- PGM1 | c.270G>A p.Q90= | Silent (SNP) | VAF 218/273 reads (80%) | catalogued as COSV64301038, COSV64301085; called by muse, mutect2, varscan2
- PIK3R6 | c.399G>A p.L133= | Silent (SNP) | VAF 22/197 reads (11%) | called by muse, mutect2, varscan2
- POLI | c.1005A>G p.K335= | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- POMC | c.573C>T p.P191= | Silent (SNP) | VAF 80/1332 reads (6%) | catalogued as COSV53034674; called by muse, mutect2
- PRDM13 | c.1422G>A p.P474= | Silent (SNP) | VAF 50/596 reads (8%) | catalogued as rs377013141; called by muse, mutect2
- PROB1 | c.810C>T p.T270= | Silent (SNP) | VAF 117/860 reads (14%) | called by muse, mutect2, varscan2
- PSD2 | c.1062C>T p.F354= | Silent (SNP) | VAF 54/440 reads (12%) | catalogued as rs774410580, COSV51205820; called by muse, mutect2, varscan2
- PTOV1 | c.51C>T p.L17= | Silent (SNP) | VAF 184/618 reads (30%) | called by muse, mutect2, varscan2
- PTPRM | c.3508C>T p.L1170= | Silent (SNP) | VAF 32/409 reads (8%) | called by muse, mutect2
- RACGAP1 | c.1017G>A p.L339= | Silent (SNP) | VAF 140/367 reads (38%) | catalogued as rs774971731; called by muse, mutect2, varscan2
- RTN3 | c.1383G>A p.L461= (on ENST00000377819 / NM_001265589.2; = p.L442= on NM_201428.3) | Silent (SNP) | VAF 89/246 reads (36%) | called by muse, mutect2, varscan2
- SDK2 | c.3144C>T p.S1048= | Silent (SNP) | VAF 142/485 reads (29%) | called by muse, mutect2, varscan2
- SH2B3 | c.1350C>T p.C450= | Silent (SNP) | VAF 338/643 reads (53%) | catalogued as rs772961717; called by muse, mutect2, varscan2
- SHPRH | c.3915A>G p.L1305= (on ENST00000275233 / NM_001042683.3; = p.L1309= on NM_173082.3) | Silent (SNP) | VAF 27/251 reads (11%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1656C>A p.A552= | Silent (SNP) | VAF 42/1040 reads (4%) | called by muse, mutect2
- SLC6A8 | c.1863A>C p.P621= | Silent (SNP) | VAF 56/434 reads (13%) | catalogued as rs782103103; called by muse, mutect2, varscan2
- SMC1B | c.219T>C p.P73= | Silent (SNP) | VAF 21/288 reads (7%) | called by muse, mutect2
- SMYD1 | c.1248C>T p.I416= | Silent (SNP) | VAF 768/769 reads (100%) | called by muse, mutect2, varscan2
- STAT3 | c.1959C>T p.I653= | Silent (SNP) | VAF 17/506 reads (3%) | called by muse, mutect2
- SUSD5 | c.459C>T p.G153= | Silent (SNP) | VAF 30/1005 reads (3%) | called by muse, mutect2
- TAF1L | c.3651G>C p.R1217= | Silent (SNP) | VAF 454/456 reads (100%) | called by muse, mutect2
- TBC1D16 | c.312C>T p.P104= | Silent (SNP) | VAF 56/839 reads (7%) | catalogued as rs751077321; called by muse, mutect2
- TDRD7 | c.2967G>A p.V989= | Silent (SNP) | VAF 37/294 reads (13%) | catalogued as rs748316297; called by muse, mutect2, varscan2
- TLR3 | c.966C>T p.F322= | Silent (SNP) | VAF 72/224 reads (32%) | called by muse, mutect2, varscan2
- TMC2 | c.2367G>A p.L789= | Silent (SNP) | VAF 41/283 reads (14%) | catalogued as COSV62651713; called by muse, mutect2, varscan2
- TMPRSS2 | c.1431G>C p.V477= | Silent (SNP) | VAF 151/708 reads (21%) | called by muse, varscan2
- TPRG1 | c.654G>A p.K218= | Silent (SNP) | VAF 22/430 reads (5%) | catalogued as rs774565222; called by muse, mutect2
- TPTE | c.1599G>A p.V533= (on ENST00000618007 / NM_199261.4; = p.V515= on NM_199259.4) | Silent (SNP) | VAF 234/724 reads (32%) | called by muse, mutect2, varscan2
- TTLL6 | c.1407G>A p.E469= (on ENST00000393382 / NM_001130918.3; = p.E162= on NM_173623.3) | Silent (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- UCHL5 | c.420C>T p.H140= | Silent (SNP) | VAF 39/106 reads (37%) | called by muse, mutect2, varscan2
- USP48 | c.2997C>G p.V999= | Silent (SNP) | VAF 58/237 reads (24%) | called by muse, mutect2, varscan2
- WNT6 | c.213C>G p.L71= | Silent (SNP) | VAF 67/840 reads (8%) | called by muse, mutect2
- XDH | c.183G>A p.L61= | Silent (SNP) | VAF 36/698 reads (5%) | called by muse, mutect2
- ZCCHC2 | c.3477C>T p.Y1159= | Silent (SNP) | VAF 57/214 reads (27%) | called by muse, mutect2, varscan2
- ZNF281 | c.2304G>T p.L768= | Silent (SNP) | VAF 178/215 reads (83%) | called by muse, mutect2, varscan2
- ZNF347 | c.903T>C p.R301= | Silent (SNP) | VAF 30/371 reads (8%) | called by muse, mutect2
- ZNF496 | c.948G>A p.L316= | Silent (SNP) | VAF 20/522 reads (4%) | called by muse, mutect2
- ZNF747 | c.171G>A p.A57= | Silent (SNP) | VAF 80/1194 reads (7%) | catalogued as COSV53223480; called by muse, mutect2
- CCDC28A-AS1 | n.424A>T | RNA (SNP) | VAF 87/313 reads (28%) | called by muse, mutect2, varscan2
- CCDC28A-AS1 | n.423G>A | RNA (SNP) | VAF 87/315 reads (28%) | called by muse, mutect2, varscan2
- CPNE1 | c.-1+1675G>A | Intron (SNP) | VAF 26/297 reads (9%) | catalogued as rs778426459, COSV58290864; called by muse, mutect2
- DVL3 | c.-110C>G | 5'UTR (SNP) | VAF 35/392 reads (9%) | called by muse, mutect2
- G3BP1 | chr5:151770493 C>A | 5'Flank (SNP) | VAF 93/682 reads (14%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+5684G>T | Intron (SNP) | VAF 120/254 reads (47%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.-224G>A | 5'UTR (SNP) | VAF 350/650 reads (54%) | catalogued as rs1261345615; called by muse, varscan2
- NXF5 | n.1371C>T | RNA (SNP) | VAF 78/532 reads (15%) | called by muse, mutect2, varscan2
- PRR34 | n.379C>A | RNA (SNP) | VAF 35/501 reads (7%) | called by muse, mutect2
- SCNN1A | chr12:6375564 G>C | 5'Flank (SNP) | VAF 26/528 reads (5%) | called by muse, mutect2
- SH3GL3 | c.45+43267C>G | Intron (SNP) | VAF 83/226 reads (37%) | catalogued as COSV100197400, COSV61057998; called by muse, mutect2, varscan2
- TAOK2 | chr16:29991567 G>C | 3'Flank (SNP) | VAF 23/530 reads (4%) | called by muse, mutect2
- TRIM9 | c.1604-4016C>T | Intron (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- TTN | c.10360+1312T>A | Intron (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
